Somatic mutation profile of tumor specimen TARGET-10-PATYWV-09A (aliquot TARGET-10-PATYWV-09A-01D) from TARGET case TARGET-10-PATYWV, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 7.7 years (2,799 days).
Specimen TARGET-10-PATYWV-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a18c93d1-cf42-41d6-ba66-a8a93776200b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PATYWV-10A (Blood Derived Normal), aliquot TARGET-10-PATYWV-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3d110e02-7588-4ec9-90ff-09a6b38a8710

The open-access MAF lists 18 somatic variants for this specimen: 13 protein-altering or splice-affecting, 3 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 12, Silent 3, Nonsense Mutation 1, Intron 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1357G>A p.E453K | Missense Mutation (SNP) | VAF 19/53 reads (36%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen possibly damaging (0.655); catalogued as rs1057519925, COSV55873816, COSV55874585; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- BRAT1 | c.1538G>A p.C513Y | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.883); catalogued as COSV61394194; called by muse, mutect2, varscan2
- DMBT1 | c.6388C>T p.R2130C (on ENST00000338354 / NM_001377530.1; = p.R1373C on NM_004406.3) | Missense Mutation (SNP) | VAF 22/41 reads (54%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.825); catalogued as rs189464773, COSV100352690, COSV57557617; called by muse, mutect2, varscan2
- GABRG3 | c.451C>T p.L151F | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.985); catalogued as COSV61523411; called by muse, mutect2, varscan2
- MSANTD2 | c.1484C>T p.A495V (on ENST00000374979 / NM_001308027.2; = p.A443V on NM_024631.4) | Missense Mutation (SNP) | VAF 11/90 reads (12%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.009); catalogued as rs766482311, COSV53450720; called by muse, mutect2, varscan2
- NOTCH1 | c.6444C>G p.S2148R | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT tolerated (0.05); PolyPhen benign (0.051); catalogued as COSV53083835; called by muse, mutect2, varscan2
- NRXN3 | c.44C>T p.P15L | Missense Mutation (SNP) | VAF 20/38 reads (53%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.931); catalogued as COSV55348461; called by muse, mutect2, varscan2
- RUNDC3B | c.1268T>C p.M423T | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV56696355; called by muse, mutect2, varscan2
- SFTPA2 | c.532G>A p.V178M | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs371035540; called by muse, mutect2, varscan2
- SLC26A5 | c.376C>A p.L126I | Missense Mutation (SNP) | VAF 24/57 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.062); catalogued as COSV59705096; called by muse, mutect2, varscan2
- THAP10 | c.586G>A p.A196T | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.875); catalogued as COSV51437103; called by muse, mutect2, varscan2
- FAM216A | c.175A>G p.K59E | Missense Mutation (SNP) | VAF 2/14 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.561); called by muse, mutect2
- IGHV3-21 | c.349_350insAGAAGTATTGA p.R117Kfs*4 | Nonsense Mutation (INS) | VAF 10/32 reads (31%) | called by pindel, varscan2
- FAN1 | c.489C>T p.Y163= | Silent (SNP) | VAF 31/64 reads (48%) | catalogued as rs779771829; called by muse, mutect2, varscan2
- HIP1 | c.2244C>T p.A748= | Silent (SNP) | VAF 23/43 reads (53%) | catalogued as rs782411470, COSV100417605; called by muse, mutect2, varscan2
- KMO | c.609C>T p.N203= | Silent (SNP) | VAF 16/37 reads (43%) | catalogued as rs146945171; called by muse, mutect2, varscan2
- OR7E24 | c.-101A>G | 5'UTR (SNP) | VAF 11/22 reads (50%) | catalogued as rs1020083224; called by muse, mutect2, varscan2
- TSC2 | c.3132-33G>A | Intron (SNP) | VAF 26/103 reads (25%) | called by muse, mutect2, varscan2
